Somatic mutation profile of tumor specimen C3L-07974-02 (aliquot CPT0486810006) from CPTAC case C3L-07974, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 75.2 years (27,477 days).
Specimen C3L-07974-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pylorus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 884f26ad-58e2-430e-8ca6-3c4c3f8eb791.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07974-31 (Blood Derived Normal), aliquot CPT0486920003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4eb44161-474a-42d1-92f5-5dd3eba64474

The open-access MAF lists 96 somatic variants for this specimen: 64 protein-altering or splice-affecting, 28 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 28, Nonsense Mutation 6, Intron 3, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.461C>G p.S154* | Nonsense Mutation (SNP) | VAF 20/169 reads (12%) | catalogued as rs1555685624, COSV61687522; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BICD1 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs755181806, COSV55673867; called by muse, mutect2
- CEP57 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 23/308 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs776303543, COSV57690890; called by muse, mutect2
- DCAF4L2 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 15/269 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60478983; called by muse, mutect2
- DOCK10 | c.3973C>T p.R1325* | Nonsense Mutation (SNP) | VAF 10/258 reads (4%) | catalogued as COSV51349418; called by muse, mutect2
- ECEL1 | c.1532G>T p.G511V | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100458932; called by muse, mutect2, varscan2
- ELFN1 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 38/493 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.828); catalogued as rs1007410261; called by muse, mutect2
- G2E3 | c.356A>G p.N119S | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.084); catalogued as rs1057389749; called by muse, mutect2, varscan2
- GABBR1 | c.2737C>T p.R913C | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1420348778, COSV100589370, COSV63541426; called by muse, mutect2
- H2AC6 | c.222C>G p.N74K | Missense Mutation (SNP) | VAF 20/357 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.967); catalogued as rs758788372, COSV58417130; called by muse, mutect2
- KCTD15 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 15/265 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs1424577588, COSV52291173; called by muse, mutect2
- KIF4B | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 38/370 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs200942753; called by muse, varscan2
- LHX3 | c.368G>A p.R123Q (on ENST00000371748 / NM_178138.6; = p.R128Q on NM_014564.5) | Missense Mutation (SNP) | VAF 13/338 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs910364399, COSV65581219; called by muse, mutect2
- LNX2 | c.326A>G p.K109R | Missense Mutation (SNP) | VAF 19/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427884051; called by muse, mutect2
- LRCH3 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.961); catalogued as rs1490274181; called by muse, mutect2, varscan2
- MAGEB5 | c.297A>C p.E99D | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs1170322916, COSV66868659; called by muse, mutect2, varscan2
- MTA1 | c.1898G>C p.R633P | Missense Mutation (SNP) | VAF 18/414 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV58758407; called by muse, mutect2
- PCDHA4 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.957); catalogued as rs781991192; called by muse, mutect2
- PGM2 | c.844A>T p.K282* | Nonsense Mutation (SNP) | VAF 18/285 reads (6%) | catalogued as rs376445794; called by muse, mutect2
- PRMT9 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.052); catalogued as rs1438582076; called by muse, mutect2, varscan2
- SCARA5 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 31/382 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1300476303, COSV57282126; called by muse, mutect2
- SCGB1D1 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 21/288 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs553664796; called by muse, mutect2
- SLAIN1 | c.1131G>C p.Q377H (on ENST00000466548; = p.Q114H on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/306 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV57388039; called by muse, mutect2
- SLC6A19 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 31/432 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs768027310; called by muse, mutect2
- SRPK1 | c.916C>G p.Q306E | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1462682664; called by muse, mutect2
- TAS2R7 | c.406G>T p.G136W | Missense Mutation (SNP) | VAF 41/375 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV53690355; called by mutect2, varscan2
- TMEM132D | c.164A>T p.N55I | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV70604758; called by muse, mutect2
- TMEM209 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 24/265 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV100390432; called by muse, mutect2
- ARHGEF38 | c.1343A>T p.N448I | Missense Mutation (SNP) | VAF 15/269 reads (6%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.96); called by muse, mutect2
- B3GNT2 | c.552G>T p.Q184H | Missense Mutation (SNP) | VAF 13/349 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.364); called by muse, mutect2
- CHD1L | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 11/260 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- CORO1A | c.1157G>A p.G386E | Missense Mutation (SNP) | VAF 14/490 reads (3%) | SIFT tolerated (0.81); PolyPhen benign (0.006); called by muse, mutect2
- DRGX | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 20/236 reads (8%) | called by muse, mutect2
- DUSP6 | c.958T>A p.Y320N | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2
- ESD | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAT4 | c.4975T>C p.S1659P | Missense Mutation (SNP) | VAF 12/307 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.387); called by muse, mutect2
- FHAD1 | c.2630A>G p.N877S | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- GLI2 | c.2267G>T p.G756V (on ENST00000361492 / NM_001374353.1; = p.G773V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/325 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- GLI3 | c.1156A>C p.T386P | Missense Mutation (SNP) | VAF 45/409 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- GRPEL2 | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HMGXB3 | c.2345C>T p.P782L (on ENST00000613459; = p.P536L on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/270 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2
- ING5 | c.532G>C p.D178H | Missense Mutation (SNP) | VAF 49/358 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IPO4 | c.2321C>A p.A774D | Missense Mutation (SNP) | VAF 34/388 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2
- KCNH1 | c.1250G>A p.S417N (on ENST00000271751 / NM_172362.3; = p.S390N on NM_002238.4) | Missense Mutation (SNP) | VAF 21/412 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.124); called by muse, mutect2
- KIAA1958 | c.2127_2131del p.G710Pfs*39 | Frame Shift Del (DEL) | VAF 16/174 reads (9%) | called by mutect2, pindel
- KIF26B | c.1190C>G p.S397C | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- LRRC53 | c.1762G>T p.E588* | Nonsense Mutation (SNP) | VAF 30/252 reads (12%) | called by mutect2, varscan2
- LSM14B | c.98C>A p.T33N | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2
- MAGEA6 | c.504A>C p.E168D | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.105); called by mutect2, varscan2
- MEP1A | c.1331T>A p.V444D | Missense Mutation (SNP) | VAF 18/488 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- MS4A14 | c.122A>G p.E41G | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- NAV3 | c.1756A>T p.R586W | Missense Mutation (SNP) | VAF 18/372 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.384); called by muse, mutect2
- NLRP11 | c.991A>T p.I331L | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.017); called by muse, mutect2
- OR52E8 | c.908A>T p.Q303L | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2
- SHLD1 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 32/342 reads (9%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC35F1 | c.1015T>G p.Y339D | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SLC45A1 | c.1735G>C p.G579R | Missense Mutation (SNP) | VAF 14/359 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SNX9 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SYNE2 | c.12257T>G p.V4086G | Missense Mutation (SNP) | VAF 29/406 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- TFAP2D | c.192C>G p.H64Q | Missense Mutation (SNP) | VAF 32/558 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.284); called by muse, mutect2
- TRPM3 | c.4832C>A p.A1611D (on ENST00000357533 / NM_001366142.2; = p.A1466D on NM_020952.6) | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); called by muse, mutect2
- UBA6 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 16/197 reads (8%) | called by muse, mutect2
- WEE2 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 20/411 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2
- ZC3H15 | c.561T>G p.I187M | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- AMER3 | c.2079C>T p.A693= | Silent (SNP) | VAF 55/428 reads (13%) | catalogued as rs758450664, COSV58467457; called by muse, mutect2, varscan2
- BCHE | c.588A>G p.L196= | Silent (SNP) | VAF 13/320 reads (4%) | called by muse, mutect2
- BIN1 | c.1413G>A p.A471= (on ENST00000316724 / NM_001320642.1; = p.A332= on NM_004305.4) | Silent (SNP) | VAF 44/361 reads (12%) | catalogued as rs371346104; called by muse, mutect2, varscan2
- C17orf113 | c.1389C>T p.D463= | Silent (SNP) | VAF 14/348 reads (4%) | catalogued as rs1006835583; called by muse, mutect2
- CBLL1 | c.519G>A p.K173= | Silent (SNP) | VAF 23/246 reads (9%) | called by muse, mutect2
- CENPB | c.1029C>A p.L343= | Silent (SNP) | VAF 53/548 reads (10%) | catalogued as rs773378239; called by muse, varscan2
- GSDMC | c.795C>A p.I265= | Silent (SNP) | VAF 14/399 reads (4%) | called by muse, mutect2
- KDM5C | c.3363G>A p.K1121= | Silent (SNP) | VAF 20/200 reads (10%) | called by muse, mutect2, varscan2
- KLHL4 | c.2001T>A p.P667= | Silent (SNP) | VAF 9/271 reads (3%) | called by muse, mutect2
- LARGE2 | c.1821G>A p.P607= | Silent (SNP) | VAF 54/472 reads (11%) | catalogued as rs200815481, COSV99138403; called by muse, mutect2, varscan2
- LGI2 | c.294G>A p.T98= | Silent (SNP) | VAF 24/276 reads (9%) | catalogued as COSV66122557; called by muse, mutect2
- LHCGR | c.1962A>G p.K654= | Silent (SNP) | VAF 36/382 reads (9%) | catalogued as rs762003062; called by muse, mutect2
- LMTK3 | c.3201C>T p.G1067= | Silent (SNP) | VAF 25/492 reads (5%) | called by muse, mutect2
- NLGN4Y | c.1221C>T p.Y407= | Silent (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- OR4P4 | c.483C>A p.T161= | Silent (SNP) | VAF 12/167 reads (7%) | catalogued as rs768719780; called by muse, mutect2
- OR56A1 | c.54C>T p.I18= | Silent (SNP) | VAF 12/353 reads (3%) | catalogued as COSV57362156; called by muse, mutect2
- PCDH10 | c.2781C>T p.N927= | Silent (SNP) | VAF 20/196 reads (10%) | called by muse, mutect2, varscan2
- PEX10 | c.426G>T p.R142= | Silent (SNP) | VAF 14/492 reads (3%) | called by muse, mutect2
- PIK3CG | c.573C>T p.R191= | Silent (SNP) | VAF 26/416 reads (6%) | catalogued as rs145944814, COSV63248832; called by muse, mutect2
- PROCR | c.255C>T p.G85= | Silent (SNP) | VAF 39/440 reads (9%) | called by muse, mutect2
- PTBP1 | c.1281C>T p.T427= (on ENST00000349038 / NM_031991.4; = p.T453= on NM_002819.5) | Silent (SNP) | VAF 34/383 reads (9%) | called by muse, mutect2
- SF3B1 | c.1326T>C p.T442= | Silent (SNP) | VAF 49/344 reads (14%) | called by muse, mutect2, varscan2
- SLIT2 | c.1905T>G p.L635= | Silent (SNP) | VAF 30/299 reads (10%) | called by muse, mutect2, varscan2
- TAF11L2 | c.318G>T p.L106= | Silent (SNP) | VAF 35/477 reads (7%) | catalogued as COSV57500324; called by muse, mutect2
- TAS2R3 | c.12C>A p.L4= | Silent (SNP) | VAF 11/201 reads (5%) | called by muse, mutect2
- WDR3 | c.1731C>T p.Y577= | Silent (SNP) | VAF 10/236 reads (4%) | catalogued as rs1270984103, COSV60468583; called by muse, mutect2
- WDR62 | c.4446C>G p.P1482= | Silent (SNP) | VAF 52/518 reads (10%) | called by muse, mutect2
- ZIC4 | c.330C>A p.P110= | Silent (SNP) | VAF 22/429 reads (5%) | catalogued as COSV101267765; called by muse, mutect2
- MAFB | c.*781C>T | 3'UTR (SNP) | VAF 26/330 reads (8%) | catalogued as COSV64826355; called by muse, mutect2
- NEB | c.11602-15730G>A | Intron (SNP) | VAF 57/766 reads (7%) | called by muse, mutect2
- PUS1 | c.304-98A>G | Intron (SNP) | VAF 22/382 reads (6%) | called by muse, mutect2
- SYT7 | c.215+8891C>A | Intron (SNP) | VAF 19/426 reads (4%) | called by muse, mutect2
